Somatic mutation profile of tumor specimen CPT000424 (aliquot CPT000424-0011) from CPTAC case 05BR052, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.3 years (22,751 days).
Specimen CPT000424: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b58c7b45-0223-4ca8-ab6d-e2ce18772198.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT000419 (Blood Derived Normal), aliquot CPT000419-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3de1122-a26d-452a-afba-91bca66d88b7

The open-access MAF lists 216 somatic variants for this specimen: 155 protein-altering or splice-affecting, 31 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 31, Intron 18, Nonsense Mutation 7, Frame Shift Del 4, RNA 4, Splice Site 4, 3'UTR 3, 5'Flank 2, 5'UTR 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.415A>T p.K139* | Nonsense Mutation (SNP) | VAF 101/220 reads (46%) | catalogued as rs1212996409, COSV52698907, COSV52754015, COSV53086342, COSV53313307; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.5132G>T p.G1711V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV67984882; called by muse, mutect2, varscan2
- AREL1 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 31/127 reads (24%) | catalogued as rs761712736, COSV62666283; called by muse, mutect2, varscan2
- ARIH2 | c.571C>G p.R191G | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV62703728, COSV62706358; called by muse, mutect2, varscan2
- BRCA1 | c.3458del p.L1153Rfs*2 | Frame Shift Del (DEL) | VAF 175/389 reads (45%) | catalogued as rs1567791573; called by mutect2, pindel, varscan2
- CACNA1C | c.6247C>G p.R2083G (on ENST00000399634 / NM_001167625.1; = p.R2012G on NM_000719.7) | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as COSV59779585; called by muse, mutect2, varscan2
- CD5 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61717983, COSV61718259; called by muse, mutect2, varscan2
- CFAP65 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774956897, COSV55390761; called by muse, varscan2
- CHRM2 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 82/587 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV57767588; called by muse, mutect2, varscan2
- COL4A2 | c.4216C>G p.P1406A | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as COSV64627026; called by muse, mutect2, varscan2
- CSF2RA | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as COSV62627072; called by muse, mutect2, varscan2
- EXOC7 | c.1963C>T p.R655C (on ENST00000335146 / NM_001145297.4; = p.R573C on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/243 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs145062268; called by muse, mutect2, varscan2
- FAM160A1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs905792693; called by muse, mutect2, varscan2
- FBN2 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52517463; called by muse, mutect2, varscan2
- FBXW10 | c.2180G>C p.R727T | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV100111733; called by muse, varscan2
- FLNB | c.3505G>T p.E1169* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV55874909; called by muse, mutect2, varscan2
- FOXRED2 | c.504G>C p.Q168H | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV53401864; called by muse, mutect2, varscan2
- GLI1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373249560, COSV57364723; called by muse, mutect2, varscan2
- IFT80 | c.1594T>G p.W532G | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100424972; called by muse, mutect2
- ITGB4 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 38/437 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs376006066; called by muse, mutect2
- ITIH2 | c.1187T>A p.I396N | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1270142244; called by muse, mutect2, varscan2
- KEL | c.1115C>A p.T372N | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.067); catalogued as rs369796448; called by muse, mutect2, varscan2
- KIAA0825 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs374186567; called by muse, mutect2, varscan2
- KNL1 | c.1522G>A p.E508K (on ENST00000346991 / NM_170589.5; = p.E482K on NM_144508.5) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as rs767135138; called by muse, mutect2, varscan2
- MACF1 | c.16448G>A p.G5483D (on ENST00000372915; = p.G3416D on NM_012090.5) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs750125936; called by muse, mutect2
- MUC16 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 72/358 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs781733130; called by muse, mutect2, varscan2
- MYLK2 | c.1649G>T p.C550F | Missense Mutation (SNP) | VAF 60/556 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs771059154; called by mutect2, varscan2
- NSUN2 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52956405; called by muse, mutect2
- OLAH | c.700C>G p.P234A (on ENST00000378228 / NM_001039702.3; = p.P287A on NM_018324.3) | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1478833469; called by muse, mutect2, varscan2
- OR1G1 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV61030311; called by muse, mutect2, varscan2
- PGBD5 | c.287C>T p.T96M (on ENST00000525115; = p.T165M on NM_001258311.2) | Missense Mutation (SNP) | VAF 67/628 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs534656022, COSV58411437; called by muse, mutect2, varscan2
- PLA2R1 | c.3674C>T p.S1225L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as COSV51777504; called by muse, mutect2, varscan2
- PRKCB | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV57778704; called by muse, mutect2, varscan2
- PTPN21 | c.3349G>C p.V1117L | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs574357713, COSV60848389; called by muse, mutect2, varscan2
- SERTAD4 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs1466528286, COSV100882589; called by muse, mutect2, varscan2
- SLC7A11 | c.561C>G p.S187R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV54927911; called by muse, mutect2, varscan2
- SUSD2 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs373308966; called by muse, mutect2, varscan2
- TFR2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs925346404; called by muse, mutect2
- TMEM130 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV59560802; called by muse, mutect2, varscan2
- TRMT2B | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100105760; called by muse, mutect2, varscan2
- TUBB8 | c.695C>G p.T232S | Missense Mutation (SNP) | VAF 99/596 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV59115711; called by muse, mutect2, varscan2
- UBXN8 | c.476C>G p.P159R | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs1563563567, COSV55664774; called by muse, mutect2, varscan2
- WDR81 | c.4522G>A p.E1508K (on ENST00000409644 / NM_001163809.2; = p.E457K on NM_152348.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as rs745403738, COSV100489190, COSV58479431; called by muse, mutect2
- ZC3H14 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748493425; called by muse, mutect2, varscan2
- ZXDC | c.2323G>T p.G775* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as COSV67628557; called by muse, mutect2, varscan2
- AAAS | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 96/827 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- ADAM18 | c.1493C>G p.T498S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADCK5 | c.931-6C>A | Splice Region (SNP) | VAF 78/410 reads (19%) | called by muse, mutect2, varscan2
- AHNAK | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKAP12 | c.2875G>C p.E959Q | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ALOX12 | c.1844T>C p.F615S | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AMD1 | c.619A>G p.S207G | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ANKRD52 | c.2678C>A p.T893N | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AP5Z1 | c.927C>G p.N309K | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.117); called by muse, mutect2
- ARHGAP24 | c.687A>T p.E229D (on ENST00000395184 / NM_001025616.3; = p.E136D on NM_031305.3) | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by mutect2, varscan2
- ARHGEF18 | c.2006A>G p.E669G (on ENST00000359920 / NM_001130955.2; = p.E565G on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARR3 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASTN2 | c.3442G>A p.E1148K (on ENST00000313400 / NM_001365069.1; = p.E1097K on NM_014010.5) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- BLMH | c.995T>A p.F332Y | Missense Mutation (SNP) | VAF 96/176 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- C1orf158 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1A | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- CBX8 | c.945C>A p.S315R | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.017); called by mutect2, varscan2
- CCDC141 | c.3515C>G p.T1172R | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCDC80 | c.269A>C p.E90A | Missense Mutation (SNP) | VAF 80/444 reads (18%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD38 | c.759A>T p.L253F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CDC73 | c.1457A>T p.D486V | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- CENPF | c.6953T>C p.L2318P | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CEP170 | c.1150G>C p.A384P | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CEP63 | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.4051A>G p.K1351E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CLEC4D | c.286T>G p.Y96D | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CORO7 | c.2038A>T p.K680* | Nonsense Mutation (SNP) | VAF 61/382 reads (16%) | called by muse, mutect2, varscan2
- CPO | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- CRB1 | c.2779T>G p.W927G | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CREBBP | c.4701G>T p.E1567D | Missense Mutation (SNP) | VAF 113/713 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CSTF2 | c.35A>C p.D12A | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- DNAH7 | c.11266A>C p.I3756L | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DSC3 | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DSE | c.427del p.D143Mfs*27 | Frame Shift Del (DEL) | VAF 18/158 reads (11%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.8156G>A p.G2719E | Missense Mutation (SNP) | VAF 110/440 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DZIP3 | c.3259A>C p.K1087Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EPHB1 | c.2531C>A p.P844H | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERICH3 | c.3788G>T p.G1263V | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- FAM185A | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- FAM193B | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- FAT1 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- FER1L6 | c.1028T>G p.L343R | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- GKAP1 | c.644A>T p.D215V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GMPPA | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GRIK3 | c.1404C>A p.D468E | Missense Mutation (SNP) | VAF 112/487 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAUS1 | c.366G>C p.L122F | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- HMCN2 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXB2 | c.347C>G p.P116R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- HPCA | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); called by muse, mutect2
- ISLR2 | c.1499T>A p.V500E | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITPKB | c.991C>G p.R331G | Missense Mutation (SNP) | VAF 77/406 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- KALRN | c.2779G>C p.E927Q | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KALRN | c.8731G>A p.A2911T (on ENST00000360013 / NM_001024660.4; = p.A1214T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/506 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNG3 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.795); called by muse, mutect2
- KIF24 | c.1240C>A p.R414S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KIF5C | c.1102A>C p.N368H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KNL1 | c.670G>C p.E224Q (on ENST00000346991 / NM_170589.5; = p.E198Q on NM_144508.5) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KNTC1 | c.2994G>T p.E998D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA5 | c.9079_9104del p.I3027Pfs*21 | Frame Shift Del (DEL) | VAF 44/254 reads (17%) | called by mutect2, varscan2
- LILRB2 | c.1642G>C p.D548H | Missense Mutation (SNP) | VAF 168/363 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC36 | c.1660+2T>G p.X554_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- MARCHF10 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 126/244 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MARCHF10 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 155/272 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MARCHF10 | c.536-1G>C p.X179_splice | Splice Site (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- MARCHF9 | c.803A>T p.K268M | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2
- ME3 | c.1150C>G p.H384D | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MED12L | c.4732G>A p.G1578R | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLLT6 | c.2354-2A>T p.X785_splice | Splice Site (SNP) | VAF 173/334 reads (52%) | called by muse, mutect2, varscan2
- MORC4 | c.1837G>C p.D613H | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- MTOR | c.4645del p.V1549Cfs*27 | Frame Shift Del (DEL) | VAF 28/150 reads (19%) | called by mutect2, pindel, varscan2
- MYH15 | c.4366C>G p.Q1456E | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MYH9 | c.2925G>C p.K975N | Missense Mutation (SNP) | VAF 92/521 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NES | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- NFIC | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 125/587 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP8 | c.2163G>C p.K721N | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NTAQ1 | c.469dup p.R157Kfs*11 | Frame Shift Ins (INS) | VAF 16/110 reads (15%) | called by mutect2, pindel, varscan2
- OR2T34 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- P2RY2 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PAN2 | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PBX2 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- PCK1 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- PCLO | c.14323A>G p.K4775E | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PKHD1 | c.4417C>G p.Q1473E | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PLIN3 | c.295G>T p.G99W | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMS2 | c.1426A>T p.S476C | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- POLG2 | c.263G>C p.R88P | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRL | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- RAPGEF4 | c.882C>G p.H294Q | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMKLB | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RIMS1 | c.554A>T p.Q185L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- RPUSD3 | c.1019C>A p.S340Y | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RSAD2 | c.742T>A p.F248I | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH2B3 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 40/219 reads (18%) | called by muse, mutect2, varscan2
- SHANK1 | c.2335C>G p.P779A | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SLC12A7 | c.1745C>G p.S582C | Missense Mutation (SNP) | VAF 60/459 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLC22A16 | c.592G>C p.A198P | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2
- SLC4A7 | c.1114T>A p.L372I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- SLC8A1 | c.1228T>G p.F410V | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- SLC8A3 | c.2407+1G>T p.X803_splice (on ENST00000381269 / NM_183002.3; = p.X801_splice on NM_033262.4) | Splice Site (SNP) | VAF 70/354 reads (20%) | called by muse, mutect2, varscan2
- SMARCB1 | c.1012G>A p.A338T (on ENST00000263121; = p.A384T on NM_003073.5) | Missense Mutation (SNP) | VAF 141/445 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SP4 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- TAS2R16 | c.782G>C p.W261S | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- TFAP2B | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM32 | c.1692G>C p.Q564H | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2
- TYW1B | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR5 | c.7595T>C p.I2532T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.365); called by muse, mutect2
- UGT2B15 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF394 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF572 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF91 | c.2351C>A p.T784N | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.113); called by muse, mutect2
- ADAMTSL5 | c.429C>T p.V143= | Silent (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- ALPK3 | c.3984G>C p.P1328= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as rs747599854; called by muse, mutect2, varscan2
- ARAP1 | c.330G>T p.G110= | Silent (SNP) | VAF 135/404 reads (33%) | called by muse, mutect2, varscan2
- AXIN2 | c.645C>T p.L215= | Silent (SNP) | VAF 17/224 reads (8%) | catalogued as rs767834824; ClinVar: likely benign / benign; called by muse, mutect2
- CCDC33 | c.735C>A p.R245= | Silent (SNP) | VAF 37/229 reads (16%) | called by muse, mutect2, varscan2
- CCN5 | c.597G>C p.T199= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as COSV51937340, COSV99509361; called by muse, mutect2, varscan2
- CFAP43 | c.1389C>T p.S463= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as rs958615814; called by muse, mutect2, varscan2
- CHUK | c.277C>T p.L93= | Silent (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- DHDH | c.297G>A p.T99= | Silent (SNP) | VAF 79/223 reads (35%) | catalogued as rs754292496, COSV55483499; called by muse, mutect2, varscan2
- FCRLA | c.997C>T p.L333= (on ENST00000367959; = p.L310= on NM_032738.4) | Silent (SNP) | VAF 41/340 reads (12%) | called by muse, mutect2, varscan2
- FLG | c.7170G>T p.G2390= | Silent (SNP) | VAF 256/810 reads (32%) | called by muse, mutect2, varscan2
- FLT4 | c.2157G>A p.E719= | Silent (SNP) | VAF 64/337 reads (19%) | catalogued as COSV56127390; called by muse, mutect2, varscan2
- GABRB1 | c.1323C>G p.P441= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as COSV54990102; called by muse, mutect2, varscan2
- H3-3A | c.69A>T p.T23= | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, varscan2
- HELZ2 | c.804G>A p.G268= | Silent (SNP) | VAF 40/268 reads (15%) | catalogued as rs1220949405, COSV64409125; called by muse, mutect2, varscan2
- HNRNPUL1 | c.321G>A p.Q107= | Silent (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- IL6ST | c.718T>C p.L240= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- ITGA7 | c.777C>T p.I259= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs756066012, COSV99145874; called by muse, mutect2, varscan2
- MFSD6 | c.999G>A p.L333= | Silent (SNP) | VAF 96/542 reads (18%) | called by mutect2, varscan2
- NADK2 | c.927T>C p.N309= (on ENST00000381937 / NM_001085411.3; = p.N146= on NM_153013.4) | Silent (SNP) | VAF 20/283 reads (7%) | called by muse, mutect2
- OR10H2 | c.585T>A p.A195= | Silent (SNP) | VAF 53/384 reads (14%) | called by muse, mutect2, varscan2
- PRRC2C | c.5101C>A p.R1701= (on ENST00000367742; = p.R1699= on NM_015172.4) | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1400478151, COSV100145948; called by muse, mutect2, varscan2
- PZP | c.1080C>G p.P360= | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- RBFOX2 | c.126C>A p.P42= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV101479339; called by muse, mutect2, varscan2
- RD3L | c.177G>A p.V59= | Silent (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- TIE1 | c.1752G>C p.L584= | Silent (SNP) | VAF 25/137 reads (18%) | called by muse, mutect2, varscan2
- TLR10 | c.267C>T p.L89= | Silent (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- TTC3 | c.1485A>G p.Q495= | Silent (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- TUFM | c.1104C>A p.G368= | Silent (SNP) | VAF 94/505 reads (19%) | called by muse, mutect2, varscan2
- UNC13A | c.4863C>T p.V1621= | Silent (SNP) | VAF 110/411 reads (27%) | called by muse, mutect2, varscan2
- ZNF786 | c.1050G>C p.G350= | Silent (SNP) | VAF 108/281 reads (38%) | called by muse, mutect2, varscan2
- AFF3 | chr2:100105561 G>A | 5'Flank (SNP) | VAF 48/270 reads (18%) | catalogued as COSV100418732; called by muse, mutect2, varscan2
- AGAP7P | n.1717G>A | RNA (SNP) | VAF 128/809 reads (16%) | called by muse, mutect2, varscan2
- AMPH | c.1159-34C>G | Intron (SNP) | VAF 9/74 reads (12%) | catalogued as COSV57750785; called by muse, mutect2, varscan2
- AP3D1 | c.2752-16C>T | Intron (SNP) | VAF 60/155 reads (39%) | called by muse, mutect2, varscan2
- APMAP | c.1042-360G>T | Intron (SNP) | VAF 36/298 reads (12%) | called by muse, mutect2, varscan2
- C22orf34 | n.145A>G | RNA (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.1931-702A>T | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as rs1554338133; called by muse, mutect2, varscan2
- CD14 | c.-23G>C | 5'UTR (SNP) | VAF 49/252 reads (19%) | called by muse, mutect2, varscan2
- CDKL1 | c.171+17299C>A | Intron (SNP) | VAF 31/171 reads (18%) | called by muse, mutect2, varscan2
- CTBP2 | c.59-2233A>C | Intron (SNP) | VAF 52/424 reads (12%) | called by muse, varscan2
- DNAH5 | c.*48A>C | 3'UTR (SNP) | VAF 32/336 reads (10%) | called by muse, mutect2
- ECRG4 | c.-10C>T | 5'UTR (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- FOXC1 | c.*26_*32del | 3'UTR (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel, varscan2
- GATM | c.1159+35G>T | Intron (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2
- HMG20B | c.147+32C>T | Intron (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- MASP1 | c.1304-4408C>T | Intron (SNP) | VAF 49/236 reads (21%) | called by muse, mutect2, varscan2
- MGAT5B | c.1025+7611T>A | Intron (SNP) | VAF 43/165 reads (26%) | called by muse, mutect2, varscan2
- MYH9 | c.1013-38C>T | Intron (SNP) | VAF 65/361 reads (18%) | called by muse, mutect2, varscan2
- NFYC-AS1 | n.415C>G | RNA (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- NMT2 | c.111-13337G>C | Intron (SNP) | VAF 43/357 reads (12%) | called by muse, mutect2, varscan2
- RARRES1 | chr3:158732493 C>G | 5'Flank (SNP) | VAF 19/191 reads (10%) | catalogued as rs536880115; called by muse, mutect2, varscan2
- RIMS2 | c.698+53077C>T | Intron (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- SH2D2A | c.123+188C>T | Intron (SNP) | VAF 88/369 reads (24%) | called by muse, mutect2, varscan2
- SMG7 | c.485-270G>A | Intron (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- SNX18 | chr5:54543351 T>C | 3'Flank (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1456G>C | 3'UTR (SNP) | VAF 30/200 reads (15%) | called by muse, mutect2, varscan2
- TTC21B | c.2950+40C>G | Intron (SNP) | VAF 23/191 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.10361-5092T>A | Intron (SNP) | VAF 53/394 reads (13%) | called by muse, mutect2, varscan2
- UBE2DNL | n.324G>A | RNA (SNP) | VAF 84/388 reads (22%) | called by muse, mutect2, varscan2
- ZNF7 | c.247+583C>G | Intron (SNP) | VAF 22/176 reads (13%) | called by muse, varscan2
